Gene-level copy-number profile of tumor specimen TCGA-EJ-7330-01A from TCGA case TCGA-EJ-7330, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.6 years (25,050 days).
Specimen TCGA-EJ-7330-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.0879d43a-3b2d-46a7-9faa-3dd9136be5c7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-7330-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/91bc0921-b65d-4f21-b91c-1070be69bf21

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 15; copy number 2: 7,647; copy number 3: 1,079; copy number 4: 43,561; copy number 5: 2,390; copy number 6: 2,307; copy number 7: 2,764; copy number 13: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-7330-01A-11D-2112-01): tumor purity 0.33, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:86,481,943–86,496,996, 1 gene: LINC02070.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:84,638,405–84,947,061, 4 genes, copy number 13 (within-gene range 5–13): LINC00971, AC117482.1, LINC02025, AC132660.2.

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
